Somatic mutation profile of tumor specimen C3N-03800-01 (aliquot CPT0285220006) from CPTAC case C3N-03800, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 35.5 years (12,965 days).
Specimen C3N-03800-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd033ca0-4281-48f6-96c6-297c004a56fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03800-31 (Blood Derived Normal), aliquot CPT0285250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9c34b6-5462-4371-b6e6-d26bdb39821a

The open-access MAF lists 34 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 5, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1368806849, COSV54107193; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 48/273 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C17orf98 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs778032171; called by muse, mutect2, varscan2
- COL6A3 | c.8866G>A p.A2956T | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.499); catalogued as rs773820329, COSV55095179; called by muse, mutect2, varscan2
- DLGAP3 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1199802242, COSV52398562; called by muse, mutect2, varscan2
- FAM83H | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 75/457 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs782236631, COSV62029239; called by muse, mutect2, varscan2
- KDM5A | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66994318; called by muse, mutect2, varscan2
- NEB | c.14293C>T p.R4765W | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs752233745; called by muse, mutect2, varscan2
- USP35 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1303740180; called by muse, mutect2, varscan2
- BOD1L1 | c.6830G>A p.G2277D | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN4 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- COL11A1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO10 | c.4179C>G p.F1393L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUF2 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SALL1 | c.3428T>C p.F1143S | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TENT5C | c.691A>T p.I231F | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VEGFC | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYND10 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CKAP2L | c.1902G>A p.K634= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- CNOT1 | c.555C>G p.L185= | Silent (SNP) | VAF 75/492 reads (15%) | called by muse, mutect2, varscan2
- DEPDC7 | c.1426C>T p.L476= (on ENST00000241051 / NM_001077242.2; = p.L467= on NM_139160.2) | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs781779175; called by muse, mutect2, varscan2
- IL1R1 | c.738G>A p.L246= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- LACTBL1 | c.354G>A p.P118= (on ENST00000618559; = p.P147= on NM_001289974.2) | Silent (SNP) | VAF 65/463 reads (14%) | catalogued as rs957277796, COSV101382408; called by muse, mutect2, varscan2
- MICALL2 | c.507G>A p.G169= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, varscan2
- SLC18B1 | c.609C>T p.C203= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs777391951, COSV51594442; called by muse, mutect2, varscan2
- STT3A | c.393G>A p.T131= | Silent (SNP) | VAF 48/278 reads (17%) | catalogued as rs751416927, COSV67064526; called by muse, mutect2, varscan2
- SYT7 | c.333C>T p.L111= | Silent (SNP) | VAF 54/295 reads (18%) | called by muse, mutect2, varscan2
- COPE | c.444-61G>A | Intron (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- DECR1 | c.69+4688G>A | Intron (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- KCP | c.486+739A>C | Intron (SNP) | VAF 44/284 reads (15%) | called by muse, mutect2, varscan2
- LINC02551 | n.1077G>A | RNA (SNP) | VAF 24/131 reads (18%) | catalogued as rs749434575; called by muse, mutect2, varscan2
- OXA1L | c.244-205G>A | Intron (SNP) | VAF 21/116 reads (18%) | catalogued as rs1019856985; called by muse, mutect2, varscan2
- RAB3GAP1 | c.*31G>A | 3'UTR (SNP) | VAF 65/356 reads (18%) | catalogued as rs1409436688; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21229G>A | Intron (SNP) | VAF 28/188 reads (15%) | catalogued as rs957225916, COSV51727551; called by muse, mutect2, varscan2
